Gene-level copy-number profile of specimen HCM-SANG-0312-C15-85A-01D-A80T-32 from HCMI case HCM-SANG-0312-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0312-C15-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c6485549-82d1-4403-b1f0-d0eb6a0b7ce9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0312-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/a237f0f8-4116-43e5-8e26-88aa9995c5e5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 46; copy number 1: 4,058; copy number 2: 52,229; copy number 3: 2,571; copy number 4: 1.

Homozygous deletions (total copy number 0; autosomes only): 43 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:186,486,253–186,680,901, 3 genes (within-gene range 0–2): ZC3H15, DPRXP1, ITGAV.
- chr2:236,037,250–236,072,556, 2 genes (within-gene range 0–2): RNU7-127P, RN7SL204P.
- chr5:59,314,110–59,529,251, 2 genes (within-gene range 0–2): AC008833.1, NDUFB4P2.
- chr6:170,695,313–170,696,950, 1 gene: AL731661.1.
- chr8:139,911,238–139,933,942, 2 genes (within-gene range 0–1): AC021744.1, C8orf17.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–1): AL359922.1.
- chr9:21,892,188–21,995,301, 4 genes (within-gene range 0–1): AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–21,996,013, 1 gene (within-gene range 0–1): AL449423.1.
- chr10:87,817,928–87,863,533, 3 genes (within-gene range 0–2): CFL1P1, RN7SL78P, KLLN.
- chr10:87,878,692–87,880,427, 1 gene (within-gene range 0–2): AC063965.2.
- chr11:46,396,414–46,594,125, 5 genes (within-gene range 0–2): AMBRA1, AC024293.1, MIR3160-1, MIR3160-2, AC127035.1.
- chr11:63,998,558–64,249,494, 17 genes (within-gene range 0–3): MACROD1, AP000721.2, AP006333.2, FLRT1, AP006333.1, STIP1, FERMT3, TRPT1, NUDT22, AP001453.1, DNAJC4, VEGFB, FKBP2, AP001453.3, PPP1R14B, PPP1R14B-AS1, AP001453.2.
- chr11:117,015,897–117,015,992, 1 gene (within-gene range 0–2): RNY4P6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,205. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
